Somatic mutation profile of tumor specimen TARGET-10-PARGHW-03A (aliquot TARGET-10-PARGHW-03A-01D) from TARGET case TARGET-10-PARGHW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 18.7 years (6,842 days).
Specimen TARGET-10-PARGHW-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4815826b-f61a-439d-9676-8ba08261853b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARGHW-10A (Blood Derived Normal), aliquot TARGET-10-PARGHW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c74d643-e1e8-4940-84eb-97ece8916890

The open-access MAF lists 21 somatic variants for this specimen: 18 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Intron 1, Silent 1, Frame Shift Ins 1, 3'Flank 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2624C>A p.T875N | Missense Mutation (SNP) | VAF 19/499 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1057520016, COSV67598981; ClinVar: likely pathogenic; called by muse, mutect2
- ANKRD24 | c.1204C>T p.R402W | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs377087098; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.928G>A p.V310I | Missense Mutation (SNP) | VAF 133/325 reads (41%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.664); catalogued as rs1280843038, COSV50053088; called by muse, mutect2, varscan2
- ECPAS | c.2390A>G p.D797G | Missense Mutation (SNP) | VAF 59/127 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as rs776454890, COSV52200772; called by muse, mutect2, varscan2
- FGFBP2 | c.460G>C p.A154P | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.679); catalogued as COSV52588515; called by muse, mutect2, varscan2
- GDF7 | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.67); PolyPhen benign (0.039); catalogued as rs1019448206, COSV55348545; called by muse, mutect2, varscan2
- GLT1D1 | c.152T>C p.I51T | Missense Mutation (SNP) | VAF 138/340 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as COSV55886982; called by muse, varscan2
- IL1A | c.128T>C p.L43P | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1433509094, COSV54520250; called by muse, mutect2
- KIAA1217 | c.5180C>A p.P1727H | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs1270811788, COSV100287248, COSV56822414; called by muse, mutect2, varscan2
- MDGA2 | c.1340G>A p.R447H (on ENST00000399232 / NM_001113498.2; = p.R149H on NM_182830.4) | Missense Mutation (SNP) | VAF 72/185 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs866090116, COSV62078847; called by muse, mutect2, varscan2
- PAX5 | c.122T>C p.I41T | Missense Mutation (SNP) | VAF 63/85 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV63912176; called by muse, mutect2, varscan2
- PRPF8 | c.3898A>G p.K1300E | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59267199; called by muse, mutect2, varscan2
- QSER1 | c.1232C>T p.P411L (on ENST00000399302; = p.P540L on NM_001076786.3) | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.115); catalogued as COSV67901658; called by muse, mutect2, varscan2
- SAMD15 | c.1019A>T p.E340V | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as COSV53627819; called by muse, mutect2, varscan2
- STMN2 | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 78/216 reads (36%) | catalogued as COSV55222009; called by muse, mutect2, varscan2
- PCDH7 | c.2396C>T p.P799L | Missense Mutation (SNP) | VAF 86/196 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SETD2 | c.5549_5550insGG p.A1851Vfs*15 | Frame Shift Ins (INS) | VAF 75/228 reads (33%) | called by mutect2, pindel, varscan2
- TRAJ28 | c.1del p.Y2Tfs*? | Frame Shift Del (DEL) | VAF 154/440 reads (35%) | called by mutect2, pindel*, varscan2
- HMCN1 | c.9252C>T p.N3084= | Silent (SNP) | VAF 76/183 reads (42%) | catalogued as rs764091385, COSV54878501; called by muse, mutect2, varscan2
- AFDN | chr6:167976167 C>G | 3'Flank (SNP) | VAF 4/26 reads (15%) | catalogued as rs77867907; called by mutect2, varscan2
- CCDC18 | c.-3+333G>C | Intron (SNP) | VAF 23/48 reads (48%) | catalogued as COSV58146173; called by muse, mutect2, varscan2
